Somatic mutation profile of tumor specimen TCGA-13-0800-01A (aliquot TCGA-13-0800-01A-01W-0371-08) from TCGA case TCGA-13-0800, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.3 years (19,087 days).
Specimen TCGA-13-0800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb6c43c2-c9a1-424a-8593-3ba380925ea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0800-10A (Blood Derived Normal), aliquot TCGA-13-0800-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/969b93dd-09d8-4957-a3f4-2500897e270c

The open-access MAF lists 76 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 13, Nonsense Mutation 5, Frame Shift Del 3, Intron 2, 5'Flank 2, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/122 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.395A>T p.K132M | Missense Mutation (SNP) | VAF 86/100 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV99547318; called by muse, mutect2
- ATR | c.7133A>T p.E2378V | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63392084; called by muse, mutect2, varscan2
- BMS1 | c.3598C>G p.R1200G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV65733941, COSV65735414; called by muse, mutect2, varscan2
- BPIFB3 | c.1059_1061del p.N353del | In Frame Del (DEL) | VAF 46/403 reads (11%) | catalogued as rs1391239091; called by pindel, varscan2
- CALCR | c.1263A>T p.Q421H (on ENST00000649521 / NM_001164737.2; = p.Q405H on NM_001742.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV64008116; called by muse, mutect2, varscan2
- CCSER2 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV99826357; called by muse, mutect2
- CFTR | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as CM950236, COSV50095732; called by muse, mutect2, varscan2
- DCT | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV65468423, COSV65470665; called by muse, mutect2, varscan2
- DMD | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 87/454 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs758235387, COSV55899741; called by muse, mutect2, varscan2
- FBXO11 | c.2479G>C p.E827Q (on ENST00000403359 / NM_001190274.2; = p.E743Q on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.746); catalogued as COSV99316706; called by muse, mutect2
- FKTN | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs137951613, COSV56312063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRK | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs762906692, COSV73384244; called by muse, mutect2, varscan2
- GLA | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 26/597 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM972780, COSV99516552; called by muse, mutect2
- HECW1 | c.4462G>A p.A1488T | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs758768640, COSV67831804; called by muse, mutect2, varscan2
- HTR1F | c.309C>A p.D103E | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60391128; called by muse, mutect2, varscan2
- LARP4 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV53327070; called by muse, mutect2, varscan2
- LGR5 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 103/545 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57007700, COSV57009735; called by muse, mutect2, varscan2
- LRCH4 | c.371A>C p.N124T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53823914; called by mutect2, varscan2
- MYBPC2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs866081511, COSV63099631; called by muse, mutect2, varscan2
- OR51A4 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66750048; called by muse, mutect2, varscan2
- PCDHGA7 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); catalogued as COSV99544704; called by mutect2, varscan2
- PDZRN3 | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55193609; called by muse, mutect2
- PI4KB | c.500T>G p.F167C (on ENST00000368873 / NM_001369623.1; = p.F179C on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/583 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55021246; called by muse, mutect2, varscan2
- PNPLA6 | c.1685G>A p.R562H (on ENST00000414982 / NM_001166111.2; = p.R514H on NM_006702.5) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs868194151, COSV55375820; called by muse, mutect2, varscan2
- PRR15L | c.288C>G p.H96Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56024620, COSV56024762; called by muse, varscan2
- PTPRT | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV61959370, COSV62017519; called by muse, mutect2, varscan2
- RAB41 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52105218; called by muse, mutect2, varscan2
- RANBP6 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52390593; called by mutect2, varscan2
- RBMX | c.559A>G p.R187G | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs1163156727, COSV57811325; called by muse, mutect2, varscan2
- RCAN3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100980358; called by muse, mutect2, varscan2
- RPN2 | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755601800, COSV52908841; called by muse, mutect2, varscan2
- RPS6KA6 | c.1019A>T p.K340I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV99425281; called by muse, mutect2
- SCAPER | c.3808G>T p.V1270F | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100239233; called by muse, mutect2
- SERPINE2 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.063); catalogued as rs549448679, COSV51459247; called by muse, mutect2
- SLC25A2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781985961, COSV53403577; called by muse, mutect2, varscan2
- SLC28A2 | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as COSV61663235, COSV61663388, COSV61665215; called by muse, mutect2, varscan2
- SNX33 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 43/351 reads (12%) | catalogued as COSV100145876; called by muse, varscan2
- TRIO | c.8667A>C p.E2889D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702686; called by muse, mutect2, varscan2
- TSPYL5 | c.1109A>C p.N370T | Missense Mutation (SNP) | VAF 113/430 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100439089; called by muse, varscan2
- ZNF180 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 15/299 reads (5%) | catalogued as COSV99660040; called by muse, mutect2
- ZNF493 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.31); catalogued as COSV62752123; called by muse, mutect2, varscan2
- ZNF614 | c.1655C>G p.S552* | Nonsense Mutation (SNP) | VAF 29/209 reads (14%) | catalogued as COSV99571903; called by muse, varscan2
- ZNF614 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 53/347 reads (15%) | catalogued as COSV99571908; called by muse, varscan2
- ZNF614 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99571909; called by muse, varscan2
- ZNF614 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99571917; called by muse, varscan2
- ZNF614 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99571920; called by muse, varscan2
- ZNF614 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99571928; called by muse, varscan2
- ZNF614 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV54548253; called by muse, mutect2, varscan2
- ZNF674 | c.726T>A p.H242Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70379741; called by muse, mutect2, varscan2
- AL645922.1 | c.2890del p.E964Kfs*7 | Frame Shift Del (DEL) | VAF 26/230 reads (11%) | called by mutect2, pindel, varscan2
- CACNA1A | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.117); called by muse, varscan2
- LRR1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NFE2L1 | c.1707G>C p.E569D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by mutect2, varscan2
- NR4A1 | c.145del p.A49Pfs*68 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- SLC12A9 | c.1853G>A p.G618D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TANC2 | c.4682C>T p.P1561L | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.058); called by mutect2, varscan2
- UBC | c.931_947del p.T311Hfs*9 | Frame Shift Del (DEL) | VAF 31/332 reads (9%) | called by pindel, varscan2
- ADGRE1 | c.2163G>A p.P721= | Silent (SNP) | VAF 180/1179 reads (15%) | catalogued as rs150705433; called by muse, mutect2, varscan2
- AIFM1 | c.1005C>G p.P335= | Silent (SNP) | VAF 92/395 reads (23%) | catalogued as rs371944474, COSV54857610; called by muse, mutect2, varscan2
- ANKMY1 | c.1149G>A p.V383= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV99802988; called by muse, mutect2, varscan2
- C19orf57 | c.51A>C p.P17= | Silent (SNP) | VAF 282/1121 reads (25%) | catalogued as COSV60970220; called by muse, mutect2, varscan2
- CANT1 | c.237C>T p.L79= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs764942510; called by muse, mutect2
- DLG4 | c.330C>G p.R110= (on ENST00000399506 / NM_001321075.3; = p.R153= on NM_001365.4) | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- DNAH8 | c.8880T>C p.R2960= | Silent (SNP) | VAF 55/439 reads (13%) | catalogued as COSV59478633; called by muse, mutect2, varscan2
- ITGA7 | c.2787C>T p.G929= (on ENST00000555728; = p.G885= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs751647692, COSV57695965, COSV57697621; called by muse, mutect2, varscan2
- NBAS | c.2514G>C p.T838= | Silent (SNP) | VAF 152/1043 reads (15%) | catalogued as COSV55737106, COSV55741449; called by muse, mutect2, varscan2
- NUAK2 | c.1152C>T p.A384= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV65682590; called by muse, mutect2, varscan2
- TCIRG1 | c.1329C>A p.G443= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV55837399; called by muse, mutect2, varscan2
- TGM2 | c.531C>T p.N177= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs1425142707, COSV63932399; called by muse, mutect2, varscan2
- ZNF614 | c.292C>T p.L98= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99571931; called by muse, mutect2, varscan2
- C1orf194 | chr1:109113638 C>A | 5'Flank (SNP) | VAF 9/54 reads (17%) | catalogued as COSV64047032; called by muse, mutect2, varscan2
- MFRP | chr11:119345801 C>A | 5'Flank (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100793518; called by muse, mutect2, varscan2
- SPEN | c.404+1197T>C | Intron (SNP) | VAF 45/168 reads (27%) | catalogued as rs761555839, COSV65367306; called by muse, mutect2, varscan2
- TOX2 | c.907-863G>A | Intron (SNP) | VAF 51/168 reads (30%) | catalogued as rs142800786; called by muse, mutect2, varscan2
